Somatic mutation profile of tumor specimen MP2PRT-PARINK-TMP1-A (aliquot MP2PRT-PARINK-TMP1-A-1-0-D-A834-36) from MP2PRT case MP2PRT-PARINK, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.9 years (3,619 days).
Specimen MP2PRT-PARINK-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e93a809a-b580-4619-b2c2-3325e904fa5e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARINK-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARINK-NB1-A-1-0-D-A834-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/06402704-98b5-40db-807a-1451899105e8

The open-access MAF lists 11 somatic variants for this specimen: 9 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 7, Silent 2, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EYA1 | c.1570G>C p.E524Q | Missense Mutation (SNP) | VAF 78/234 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.457); catalogued as CM081587; called by muse, mutect2, varscan2
- LNX2 | c.1034G>A p.R345Q | Missense Mutation (SNP) | VAF 166/457 reads (36%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.871); catalogued as rs201011254, COSV60334324; called by muse, mutect2, varscan2
- MTO1 | c.937C>T p.R313* | Nonsense Mutation (SNP) | VAF 58/164 reads (35%) | catalogued as COSV64774134; called by muse, mutect2, varscan2
- SMARCA1 | c.578G>T p.W193L | Missense Mutation (SNP) | VAF 111/295 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1223901326, COSV64413769; called by muse, mutect2, varscan2
- ARX | c.158C>T p.P53L | Missense Mutation (SNP) | VAF 242/646 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- BCL9 | c.2522T>A p.L841Q | Missense Mutation (SNP) | VAF 456/1106 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- FBXO41 | c.856C>T p.L286F | Missense Mutation (SNP) | VAF 188/481 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPI1 | c.360_361insAGGGG p.Y121Rfs*67 | Frame Shift Ins (INS) | VAF 139/410 reads (34%) | called by mutect2, pindel, varscan2
- THBS3 | c.559A>C p.M187L | Missense Mutation (SNP) | VAF 118/300 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- BCL9 | c.2523G>A p.L841= | Silent (SNP) | VAF 464/1109 reads (42%) | catalogued as COSV52340845; called by muse, mutect2, varscan2
- CBLL2 | c.315G>A p.A105= | Silent (SNP) | VAF 47/627 reads (7%) | catalogued as rs769753747; called by muse, mutect2
